Somatic mutation profile of tumor specimen MP2PRT-PAPRFR-TMP1-A (aliquot MP2PRT-PAPRFR-TMP1-A-1-0-D-A83A-36) from MP2PRT case MP2PRT-PAPRFR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.3 years (468 days).
Specimen MP2PRT-PAPRFR-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 67a16e68-a752-4588-ae62-c541f926ea93.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPRFR-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPRFR-NB1-A-1-0-D-A83A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/656adc7e-0248-4098-abed-cd520f498971

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Nonsense Mutation 2, Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- F5 | c.6163C>T p.R2055* | Nonsense Mutation (SNP) | VAF 64/289 reads (22%) | catalogued as rs199690772, COSV63124791; called by muse, mutect2, varscan2
- LRFN2 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 94/392 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.322); catalogued as COSV57827803; called by muse, mutect2, varscan2
- NRCAM | c.3403C>T p.R1135* | Nonsense Mutation (SNP) | VAF 96/412 reads (23%) | catalogued as rs201318713, COSV61034719; called by muse, varscan2
- SYT12 | c.603G>T p.Q201H | Missense Mutation (SNP) | VAF 72/330 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- BSN | c.10860C>T p.Y3620= | Silent (SNP) | VAF 36/450 reads (8%) | catalogued as rs371074643; called by muse, mutect2
